Somatic mutation profile of tumor specimen ALCH-B3XW-TTP1-A (aliquot ALCH-B3XW-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3XW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.2 years (24,551 days).
Specimen ALCH-B3XW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7a9e90d-1037-475d-b211-6a49f45205ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3XW-NB1-A (Blood Derived Normal), aliquot ALCH-B3XW-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c81946c-c9f6-472e-95fa-1e4132706c6a

The open-access MAF lists 509 somatic variants for this specimen: 348 protein-altering or splice-affecting, 100 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 290, Silent 100, Intron 31, Nonsense Mutation 23, Frame Shift Del 14, RNA 12, Splice Site 11, 3'UTR 11, Splice Region 5, Frame Shift Ins 4, 5'UTR 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 115/475 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 55/284 reads (19%) | catalogued as rs1555525970, COSV52662121, COSV52858115, COSV53050787, COSV53082360; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 45/268 reads (17%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- ABCA13 | c.12022C>A p.P4008T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV71289741; called by muse, mutect2, varscan2
- ADAMTS12 | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1213708496; called by muse, mutect2, varscan2
- ADAMTS20 | c.3470G>T p.R1157L | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67130038; called by muse, mutect2, varscan2
- ADAMTS3 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs143059623; called by muse, mutect2, varscan2
- ADCY8 | c.2497C>A p.P833T | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs747305191; called by muse, mutect2, varscan2
- ANK1 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 92/497 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs201000616; called by muse, mutect2, varscan2
- ANP32E | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 100/243 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1440739917; called by muse, mutect2, varscan2
- ARHGEF17 | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as rs145994191; called by muse, mutect2, varscan2
- ARID1B | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious, low confidence (0.01); catalogued as rs1345582885; called by muse, varscan2
- ASCL1 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.68); catalogued as rs749888158, COSV99902100; called by muse, mutect2, varscan2
- ATP10A | c.4196G>T p.G1399V | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV63517696; called by muse, mutect2, varscan2
- BEGAIN | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410639410; called by muse, mutect2, varscan2
- BRDT | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.46); catalogued as COSV62866490; called by muse, mutect2, varscan2
- C8orf34 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 26/427 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs561667412, COSV61378579; called by muse, mutect2
- CAMP | c.280C>T p.Q94* (on ENST00000296435; = p.Q91* on NM_004345.5) | Nonsense Mutation (SNP) | VAF 50/247 reads (20%) | catalogued as rs533541556, COSV56482199; called by muse, mutect2, varscan2
- CASS4 | c.1820A>T p.K607M | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs758545822; called by muse, mutect2, varscan2
- CD200 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 90/538 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); catalogued as COSV59863416; called by muse, mutect2, varscan2
- CDH18 | c.1113G>T p.K371N | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV56942399; called by muse, mutect2
- CDH18 | c.29G>C p.C10S | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); catalogued as rs189671590, COSV56930223; called by muse, mutect2, varscan2
- CFH | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as CM1512038, COSV62777841; called by muse, mutect2, varscan2
- CNGA3 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV55622215; called by muse, mutect2, varscan2
- CNTNAP4 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV56667545; called by muse, mutect2, varscan2
- COL14A1 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs765094607; called by muse, mutect2
- CTNND2 | c.285G>T p.M95I | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58927005; called by muse, mutect2, varscan2
- CUL3 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52362281, COSV52371404; called by muse, mutect2, varscan2
- CXCR3 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.055); catalogued as COSV65461770; called by muse, mutect2, varscan2
- DCAF12L1 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV64421908; called by muse, mutect2
- DCC | c.3797C>G p.P1266R | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.975); catalogued as COSV71427593, COSV71438411; called by muse, mutect2, varscan2
- DKK2 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 92/387 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1205531480; called by muse, mutect2, varscan2
- DLG2 | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711935; called by muse, mutect2, varscan2
- DNAH8 | c.1499C>A p.S500Y | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV59464656; called by muse, mutect2, varscan2
- DOCK10 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs1306830146, COSV99291845; called by muse, mutect2, varscan2
- DSCAM | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 45/186 reads (24%) | catalogued as rs1461810166, COSV68027236; called by muse, mutect2, varscan2
- EFNA1 | c.487_489del p.E163del | In Frame Del (DEL) | VAF 24/229 reads (10%) | catalogued as rs748652115; called by mutect2, pindel, varscan2
- EVA1A | c.344C>A p.A115E | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV52057174; called by muse, mutect2, varscan2
- F8 | c.1595G>T p.W532L | Missense Mutation (SNP) | VAF 100/420 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as CM062691; called by muse, varscan2
- FAM135B | c.2195A>G p.H732R | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs202075652; called by muse, mutect2, varscan2
- FAT3 | c.1777G>T p.V593F | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99964156; called by muse, mutect2
- FMN2 | c.3692G>T p.G1231V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (1); catalogued as COSV60418826; called by muse, mutect2, varscan2
- FOXG1 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1309285440, COSV100486878, COSV57396187; called by muse, mutect2, varscan2
- GABBR2 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as rs76761930; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLP2R | c.309C>A p.Y103* | Nonsense Mutation (SNP) | VAF 65/330 reads (20%) | catalogued as rs145472633; called by muse, mutect2, varscan2
- GLUD2 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100047105; called by muse, mutect2, varscan2
- GNB1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV66100626; called by muse, mutect2, varscan2
- GPAT4 | c.911+1G>T p.X304_splice | Splice Site (SNP) | VAF 34/166 reads (20%) | catalogued as rs778109201; called by muse, mutect2, varscan2
- GPR31 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV64761204; called by muse, mutect2, varscan2
- GREB1L | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs202059916; called by muse, mutect2, varscan2
- GRM2 | c.1612G>C p.A538P | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.546); catalogued as COSV99622763; called by muse, mutect2, varscan2
- GRXCR1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as COSV67669920; called by muse, mutect2, varscan2
- HEPHL1 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539757301; called by muse, mutect2, varscan2
- HMX3 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs576562691; called by muse, mutect2, varscan2
- IGKV4-1 | c.339C>A p.Y113* | Nonsense Mutation (SNP) | VAF 34/184 reads (18%) | catalogued as rs1134821; called by muse, mutect2, varscan2
- IL1RAPL1 | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56290436; called by muse, mutect2, varscan2
- IQUB | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as rs182978338, COSV61242313, COSV61243166; called by muse, mutect2, varscan2
- ITK | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs767660056; called by muse, mutect2, varscan2
- L1CAM | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs781866909, COSV100649361, COSV62829344; called by muse, mutect2, varscan2
- LAS1L | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56709269; called by muse, mutect2, varscan2
- LVRN | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776132785; called by muse, mutect2, varscan2
- MAG | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100728025; called by muse, mutect2, varscan2
- MARCHF6 | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs752643750; called by muse, mutect2, varscan2
- METTL15 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57723737; called by muse, mutect2, varscan2
- MOS | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as rs1444910904; called by muse, mutect2, varscan2
- MS4A14 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100280698; called by muse, mutect2, varscan2
- MUC4 | c.10559C>G p.P3520R | Missense Mutation (SNP) | VAF 92/870 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.811); catalogued as rs771736884; called by muse, varscan2
- MYH1 | c.4428G>C p.K1476N | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1386502889, COSV99876572; called by muse, mutect2, varscan2
- NEUROD4 | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54472982; called by muse, mutect2, varscan2
- NLRP14 | c.1291G>C p.A431P | Missense Mutation (SNP) | VAF 118/553 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55064710; called by muse, mutect2, varscan2
- OR11A1 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.115); catalogued as COSV101010693; called by muse, mutect2, varscan2
- OR11L1 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV63314300; called by muse, mutect2, varscan2
- OR13C9 | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV52241290; called by muse, mutect2, varscan2
- OR2B2 | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs958294160; called by muse, mutect2, varscan2
- OR2J1 | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101013723; called by muse, mutect2, varscan2
- OR2T11 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100424990, COSV58185741; called by muse, mutect2, varscan2
- OR4D10 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV73260217; called by muse, mutect2, varscan2
- OR4M1 | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 78/688 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100271216; called by muse, mutect2, varscan2
- OR5M11 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1417256854, COSV101602025; called by muse, mutect2, varscan2
- OR6F1 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128955; called by muse, mutect2
- PAXBP1 | c.1639G>A p.G547S | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as rs1183420676; called by muse, mutect2
- PCDH11X | c.1552C>A p.R518S | Missense Mutation (SNP) | VAF 82/620 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.932); catalogued as COSV53486709; called by muse, mutect2, varscan2
- PCDHA2 | c.1292del p.G431Afs*18 | Frame Shift Del (DEL) | VAF 47/260 reads (18%) | catalogued as COSV65364210; called by mutect2, pindel, varscan2
- PCDHB6 | c.1675G>C p.V559L | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV50692259; called by muse, mutect2, varscan2
- PCDHB7 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1554279859; called by muse, mutect2, varscan2
- PCDHGB5 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV53905407; called by muse, mutect2, varscan2
- PCLO | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV61673842; called by muse, mutect2, varscan2
- PGK1 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 123/465 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV59372745; called by muse, mutect2, varscan2
- PIPOX | c.263+1G>A p.X88_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100037985; called by muse, mutect2, varscan2
- PKDREJ | c.5042G>A p.R1681Q | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as rs1319017194, COSV53549418; called by muse, mutect2, varscan2
- PKHD1L1 | c.12155C>G p.P4052R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV101006625; called by muse, mutect2, varscan2
- PNMA3 | c.979G>T p.V327L | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.341); catalogued as rs1410844544; called by muse, mutect2, varscan2
- RBMXL3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs782559248; called by muse, mutect2, varscan2
- RCN1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV50014326; called by muse, mutect2, varscan2
- REV1 | c.3311G>T p.G1104V | Missense Mutation (SNP) | VAF 91/447 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV51489912; called by muse, mutect2, varscan2
- RYR2 | c.3164G>T p.R1055L | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV63664528, COSV63713105; called by muse, mutect2, varscan2
- SBF1 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs775997323, COSV62366927; called by muse, mutect2, varscan2
- SEC16A | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs759700590; called by muse, mutect2, varscan2
- SETD1B | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 37/269 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1398255970; called by muse, mutect2, varscan2
- SI | c.3252C>A p.V1084= | Splice Region (SNP) | VAF 32/284 reads (11%) | catalogued as COSV52264427, COSV52295900; called by muse, mutect2
- SLC17A8 | c.38T>A p.I13N | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV60123617; called by muse, mutect2, varscan2
- SLC5A11 | c.471G>T p.K157N | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV61740767; called by muse, mutect2, varscan2
- SMAD9 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63206743; called by muse, mutect2, varscan2
- SMG8 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV99959087; called by muse, mutect2, varscan2
- SOX17 | c.518G>C p.R173P | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV52024261; called by muse, mutect2, varscan2
- SPON1 | c.1917del p.M640Cfs*50 | Frame Shift Del (DEL) | VAF 43/238 reads (18%) | catalogued as COSV59963647; called by mutect2, pindel, varscan2
- SRRM4 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.066); catalogued as rs368181623; called by muse, mutect2, varscan2
- STPG2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1030928353; called by muse, mutect2, varscan2
- SYNE1 | c.8222G>A p.R2741K (on ENST00000367255 / NM_182961.4; = p.R2748K on NM_033071.3) | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs181218387; called by muse, mutect2, varscan2
- SYT1 | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693543; called by muse, mutect2
- TKTL2 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54921043; called by muse, mutect2, varscan2
- TPO | c.1061C>A p.A354E | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.053); catalogued as rs766827032; called by muse, mutect2, varscan2
- TRPC5 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99461925; called by muse, mutect2, varscan2
- TRPM1 | c.3061+1G>A p.X1021_splice | Splice Site (SNP) | VAF 30/265 reads (11%) | catalogued as rs749930261, CS0911419; called by muse, mutect2, varscan2
- VIM | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 126/665 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV56406138; called by muse, mutect2, varscan2
- VWA5B1 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 43/188 reads (23%) | catalogued as rs377578195; called by muse, mutect2, varscan2
- ZACN | c.374+3_374+6del p.X125_splice | Splice Site (DEL) | VAF 28/124 reads (23%) | catalogued as rs549500563; called by mutect2, pindel, varscan2
- ZNF180 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs759634657; called by muse, mutect2, varscan2
- ZNF208 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.96); catalogued as COSV68100443; called by muse, mutect2, varscan2
- ZNF283 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV61032250; called by muse, mutect2, varscan2
- ZNF526 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 75/388 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs750543861, COSV55900057; called by muse, mutect2, varscan2
- ZNF565 | c.1336C>T p.L446F (on ENST00000355114; = p.L406F on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1337199668; called by muse, mutect2
- ZNF69 | c.131C>T p.S44F (on ENST00000429654 / NM_001364730.1; = p.S30F on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV60902998, COSV60903417; called by muse, mutect2, varscan2
- ZNF75D | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 99/387 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1556421530, COSV66132652; called by muse, mutect2, varscan2
- ZSCAN23 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57043511; called by muse, mutect2, varscan2
- ZXDA | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV62387546; called by muse, mutect2, varscan2
- A2M | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- AACS | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ABCA4 | c.3500A>T p.Q1167L | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOT11 | c.1029+1del p.X343_splice | Splice Site (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- ADAMTS12 | c.2640G>T p.K880N | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AFF2 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- AFF2 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ALPK2 | c.5035G>A p.G1679S | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANK2 | c.2179-2del p.X727_splice | Splice Site (DEL) | VAF 28/179 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD34C | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- BCORL1 | c.3001del p.Q1001Rfs*49 | Frame Shift Del (DEL) | VAF 97/322 reads (30%) | called by mutect2, varscan2
- BGN | c.593G>T p.S198I | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- BNC2 | c.2681A>T p.K894I | Missense Mutation (SNP) | VAF 134/432 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- BRINP1 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- BRINP3 | c.2216T>A p.V739E | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BRWD3 | c.3482-1G>T p.X1161_splice | Splice Site (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
- BTNL9 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- CALN1 | c.294G>T p.M98I (on ENST00000329008 / NM_001017440.3; = p.M140I on NM_031468.4) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CALR | c.103T>G p.S35A | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CAMTA1 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CASP5 | c.596G>A p.C199Y | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CATSPERB | c.713-1G>C p.X238_splice | Splice Site (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- CCDC136 | c.2319C>G p.Y773* | Nonsense Mutation (SNP) | VAF 89/451 reads (20%) | called by muse, mutect2, varscan2
- CCDC168 | c.2473G>T p.G825* | Nonsense Mutation (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- CCDC175 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, varscan2
- CCDC73 | c.3043C>T p.P1015S | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CCL4L2 | c.192-4C>A | Splice Region (SNP) | VAF 62/454 reads (14%) | called by muse, mutect2, varscan2
- CCN6 | c.424A>G p.S142G | Missense Mutation (SNP) | VAF 85/682 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, varscan2
- CCNJ | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CD163L1 | c.3853C>A p.Q1285K | Missense Mutation (SNP) | VAF 98/640 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CDH18 | c.1556A>T p.N519I | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CDH20 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 86/426 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1044dup p.A349Cfs*2 | Frame Shift Ins (INS) | VAF 72/419 reads (17%) | called by mutect2, pindel, varscan2
- CELF4 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHEK2 | c.1239del p.H414Tfs*11 (on ENST00000382580 / NM_001005735.2; = p.H371Tfs*11 on NM_007194.4) | Frame Shift Del (DEL) | VAF 39/200 reads (20%) | called by mutect2, pindel, varscan2
- CHRND | c.771C>G p.C257W | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNRIP1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- COL11A2 | c.2845G>A p.G949R (on ENST00000341947 / NM_080680.3; = p.G842R on NM_080679.2) | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A6 | c.4805C>A p.S1602Y | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.5488del p.S1830Pfs*3 (on ENST00000312481; = p.S1826Pfs*3 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 65/313 reads (21%) | called by mutect2, pindel, varscan2
- CRHR2 | c.1075T>A p.Y359N | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSF2RB | c.1797C>A p.S599R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CUL4B | c.1768A>T p.I590F | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CYLC1 | c.1914T>A p.Y638* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- CYLD | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DEPDC5 | c.2038G>C p.D680H (on ENST00000400246; = p.D749H on NM_014662.5) | Missense Mutation (SNP) | VAF 57/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIPK1B | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLC1 | c.3172G>T p.V1058L (on ENST00000276297 / NM_001348081.2; = p.V621L on NM_006094.5) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- DLG2 | c.1223C>G p.T408S | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- DNAH11 | c.1685G>A p.C562Y | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DOCK10 | c.5983del p.E1995Sfs*9 | Frame Shift Del (DEL) | VAF 52/207 reads (25%) | called by mutect2, pindel, varscan2
- DPP10 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DRC7 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- EBF4 | c.191G>T p.R64M (on ENST00000609451; = p.R60M on NM_001110514.1) | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- EDEM2 | c.1156del p.D386Ifs*5 | Frame Shift Del (DEL) | VAF 41/207 reads (20%) | called by mutect2, pindel, varscan2
- ENPP2 | c.1846A>G p.T616A (on ENST00000075322 / NM_001040092.3; = p.T668A on NM_006209.5) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L3 | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- EPHA7 | c.411T>A p.N137K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHX4 | c.670T>C p.W224R | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EYS | c.2980C>A p.P994T | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- FAM135B | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FAT3 | c.2618A>T p.D873V | Missense Mutation (SNP) | VAF 70/331 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- FBXL18 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FXR2 | c.1528+1G>A p.X510_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- GAS2L3 | c.1606C>A p.Q536K | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA10 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- GLO1 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2
- GM2A | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2, varscan2
- GRM5 | c.2479G>C p.A827P | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GRM5 | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HEPH | c.2041A>T p.T681S (on ENST00000343002; = p.T414S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HLA-DRA | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 111/416 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- HMGN5 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- HS6ST2 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HSPA14 | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HTRA1 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HTRA4 | c.848del p.P283Hfs*25 | Frame Shift Del (DEL) | VAF 69/402 reads (17%) | called by mutect2, pindel, varscan2
- HUNK | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- IGHE | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGHV3-74 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- IGKV2D-24 | c.57T>A p.S19R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IGSF1 | c.2107T>C p.C703R | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1987C>A p.Q663K | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITIH5 | c.2789C>G p.T930R | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- KIF7 | c.1702del p.L568Wfs*31 | Frame Shift Del (DEL) | VAF 58/284 reads (20%) | called by mutect2, pindel, varscan2
- KLHL29 | c.2220G>T p.E740D | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KLHL4 | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 45/321 reads (14%) | called by muse, mutect2, varscan2
- KLHL6 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 175/648 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- KNL1 | c.4549A>T p.K1517* (on ENST00000346991 / NM_170589.5; = p.K1491* on NM_144508.5) | Nonsense Mutation (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- L1CAM | c.3082G>T p.G1028C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMA1 | c.8338G>T p.G2780C | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARGE2 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- LAS1L | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LASP1 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LINC00634 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 41/230 reads (18%) | PolyPhen benign (0.139); called by muse, mutect2, varscan2
- LMOD2 | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, varscan2
- LRBA | c.3553T>A p.S1185T | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRTM1 | c.1285G>T p.V429F | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LSAMP | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 80/479 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- LUC7L3 | c.*34-7G>T | Splice Region (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- LYZL1 | c.419G>T p.C140F (on ENST00000375500; = p.C94F on NM_032517.6) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LYZL4 | c.381_383delinsCG p.W127Cfs*? | Frame Shift Del (DEL) | VAF 20/181 reads (11%) | called by pindel, varscan2*
- MAGEB18 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- MALRD1 | c.3201G>T p.M1067I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2K3 | c.429G>T p.M143I (on ENST00000342679 / NM_145109.3; = p.M114I on NM_002756.4) | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2
- MAP3K1 | c.3568G>T p.A1190S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MDH1 | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MED12 | c.5141T>A p.V1714E | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MGAT4C | c.745T>A p.W249R | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP16 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRC1 | c.2102G>C p.R701P | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- MSC | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MTERF1 | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 53/254 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.31359G>C p.Q10453H | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MYH1 | c.2726G>T p.C909F | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- MYH2 | c.3448G>T p.E1150* | Nonsense Mutation (SNP) | VAF 80/431 reads (19%) | called by muse, mutect2, varscan2
- NADK2 | c.743A>G p.H248R (on ENST00000381937 / NM_001085411.3; = p.H85R on NM_153013.4) | Missense Mutation (SNP) | VAF 118/531 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NBEA | c.1060G>C p.G354R | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDNF | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- NETO2 | c.1250A>C p.E417A | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- NEUROD4 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NGEF | c.503G>C p.W168S | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- NKAP | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NOL6 | c.2365-3_2370del p.X789_splice | Splice Site (DEL) | VAF 43/117 reads (37%) | called by mutect2, pindel
- NOS1 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP37 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP98 | c.1205A>C p.N402T | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- OR2L13 | c.263dup p.K89Efs*22 | Frame Shift Ins (INS) | VAF 98/300 reads (33%) | called by mutect2, pindel, varscan2
- OR3A1 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR4C46 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR51F2 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51L1 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- OR52A5 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- OR5M11 | c.11C>G p.T4R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- OR7G1 | c.274A>C p.I92L | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- PAX9 | c.881C>G p.S294C | Missense Mutation (SNP) | VAF 101/516 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PAXBP1 | c.981A>T p.Q327H | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCDHB6 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK6 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- PDZRN4 | c.2078C>A p.T693K (on ENST00000402685 / NM_001164595.2; = p.T435K on NM_013377.4) | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHETA1 | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PIEZO2 | c.6547T>C p.Y2183H | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PJA1 | c.1214C>G p.P405R (on ENST00000361478 / NM_145119.4; = p.P217R on NM_022368.5) | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PLCZ1 | c.1707del p.Q570Nfs*9 | Frame Shift Del (DEL) | VAF 40/273 reads (15%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.864C>T p.L288= | Splice Region (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- PRDM13 | c.186dup p.S63Lfs*51 | Frame Shift Ins (INS) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- PRDM9 | c.1822T>A p.Y608N | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PRKG1 | c.431G>T p.C144F | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRRC2B | c.3162G>C p.E1054D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRSS16 | c.366G>T p.W122C | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRU | c.2905G>T p.V969F | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- PUM1 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PZP | c.2633T>A p.V878E | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- RAD51C | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 60/333 reads (18%) | called by muse, mutect2, varscan2
- RASGRP3 | c.1357C>A p.P453T (on ENST00000402538 / NM_001349975.2; = p.P452T on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBBP6 | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- RIN3 | c.1525G>T p.G509W | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF128 | c.910G>T p.V304F (on ENST00000255499 / NM_194463.2; = p.V278F on NM_024539.3) | Missense Mutation (SNP) | VAF 72/314 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RNF157 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RPS6KA6 | c.1008+2T>A p.X336_splice | Splice Site (SNP) | VAF 32/152 reads (21%) | called by muse, mutect2, varscan2
- RTL4 | c.513A>T p.Q171H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SAA2 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2
- SAFB | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAPER | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SCN9A | c.5880T>A p.S1960R (on ENST00000303354; = p.S1949R on NM_002977.3) | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SCRT2 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SELENOS | c.408+3_408+4insT | Splice Region (INS) | VAF 20/90 reads (22%) | called by mutect2, pindel*, varscan2
- SERPINI1 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SFMBT2 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIPA1L1 | c.4351G>C p.A1451P | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.649); called by muse, varscan2
- SLBP | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC15A4 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC17A2 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 56/569 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SLC2A14 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SLC41A2 | c.1380del p.F460Lfs*5 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- SLC41A2 | c.826A>T p.I276L | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2
- SLC46A3 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- SLC5A4 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC9A6 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLITRK4 | c.2470T>A p.Y824N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK4 | c.1375A>G p.N459D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SLITRK4 | c.1335T>G p.F445L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SMC6 | c.3099A>G p.I1033M | Missense Mutation (SNP) | VAF 85/429 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SMTNL2 | c.1254G>A p.M418I (on ENST00000389313 / NM_001114974.2; = p.M274I on NM_198501.3) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SNTB1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.235); called by muse, mutect2
- SOCS5 | c.856A>G p.T286A | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SORCS1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA31A1 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 184/1131 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SPATA7 | c.1201A>C p.K401Q | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SSH1 | c.3142A>G p.K1048E | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ST18 | c.1279C>A p.R427S | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAG2 | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SYNE1 | c.1403G>T p.R468L (on ENST00000367255 / NM_182961.4; = p.R475L on NM_033071.3) | Missense Mutation (SNP) | VAF 113/416 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- TCIRG1 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX15 | c.2002G>A p.V668I (on ENST00000256246; = p.V1051I on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- THSD7A | c.1608A>T p.K536N | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- TLR6 | c.1914A>T p.R638S | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TMEM132C | c.2522A>T p.Y841F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TPP1 | c.1518del p.R506Sfs*13 | Frame Shift Del (DEL) | VAF 79/380 reads (21%) | called by mutect2, pindel, varscan2
- TPTE2 | c.391G>T p.G131W (on ENST00000400230 / NM_199254.2; = p.G94* on NM_130785.3) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TRIM49C | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM64C | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM77 | c.612A>C p.E204D | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC23 | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.355); called by muse, mutect2
- TTN | c.17988T>A p.S5996R (on ENST00000591111; = p.S5069R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | PolyPhen benign (0.241); called by muse, mutect2, varscan2
- TTN | c.11611G>T p.A3871S (on ENST00000591111; = p.A3825S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- TVP23C | c.605T>G p.I202S | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXNRD1 | c.1384A>T p.K462* (on ENST00000525566 / NM_001093771.3; = p.K364* on NM_003330.4) | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.734dup p.L245Ffs*3 | Frame Shift Ins (INS) | VAF 18/173 reads (10%) | called by mutect2, pindel
- UQCC3 | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- UTP20 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.222); called by muse, mutect2
- WDR72 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 126/534 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZBED9 | c.2559G>T p.L853F | Missense Mutation (SNP) | VAF 80/453 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZC3H12B | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZCCHC14 | c.2524G>C p.G842R (on ENST00000268616; = p.G979R on NM_015144.3) | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF330 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZNF479 | c.1365C>A p.H455Q | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.209); called by mutect2, varscan2
- ZNF532 | c.3563A>T p.Q1188L | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ZNF534 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF729 | c.2382A>T p.K794N | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZNF805 | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 103/579 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ADAMTS20 | c.1737A>T p.A579= | Silent (SNP) | VAF 87/530 reads (16%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.378C>T p.D126= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as rs964658741; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.123C>A p.A41= | Silent (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- ADIPOQ | c.351G>T p.V117= | Silent (SNP) | VAF 86/225 reads (38%) | called by muse, mutect2, varscan2
- AKAP1 | c.2004G>A p.L668= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as COSV58471537; called by muse, mutect2, varscan2
- APLP1 | c.1128C>T p.H376= | Silent (SNP) | VAF 60/287 reads (21%) | catalogued as rs760054625; called by muse, mutect2, varscan2
- APOB | c.573C>T p.T191= | Silent (SNP) | VAF 96/555 reads (17%) | catalogued as rs202005055; ClinVar: benign; called by muse, mutect2, varscan2
- CACNA1F | c.1473T>A p.A491= | Silent (SNP) | VAF 27/87 reads (31%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.747A>G p.A249= | Silent (SNP) | VAF 40/236 reads (17%) | called by muse, mutect2, varscan2
- CCSER1 | c.2523G>C p.T841= | Silent (SNP) | VAF 39/135 reads (29%) | called by muse, mutect2, varscan2
- CEACAM3 | c.456C>A p.A152= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- CMKLR1 | c.423G>T p.V141= (on ENST00000312143 / NM_001142344.2; = p.V139= on NM_004072.3) | Silent (SNP) | VAF 49/285 reads (17%) | called by muse, mutect2, varscan2
- CRB2 | c.343C>A p.R115= | Silent (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
- CTC1 | c.3528A>G p.L1176= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as COSV100236582; called by muse, mutect2, varscan2
- DAGLB | c.201A>C p.A67= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV99765985; called by muse, mutect2, varscan2
- DCAF12L1 | c.1290G>C p.A430= | Silent (SNP) | VAF 50/270 reads (19%) | catalogued as rs755096870, COSV64421685; called by muse, mutect2, varscan2
- DCAF12L2 | c.117C>A p.P39= | Silent (SNP) | VAF 117/450 reads (26%) | catalogued as COSV100758822; called by muse, mutect2, varscan2
- DCSTAMP | c.465C>G p.A155= | Silent (SNP) | VAF 44/196 reads (22%) | called by muse, mutect2, varscan2
- DNAAF3 | c.1416A>T p.G472= (on ENST00000524407 / NM_001256715.2; = p.G519= on NM_178837.4) | Silent (SNP) | VAF 51/193 reads (26%) | called by muse, mutect2, varscan2
- ENTPD4 | c.762A>T p.G254= | Silent (SNP) | VAF 78/230 reads (34%) | called by muse, mutect2, varscan2
- ESCO1 | c.2463G>A p.Q821= | Silent (SNP) | VAF 36/171 reads (21%) | catalogued as rs890276548; called by muse, mutect2, varscan2
- ESCO1 | c.636A>G p.T212= | Silent (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- FAM149A | c.996A>G p.K332= (on ENST00000356371 / NM_001367768.2; = p.K41= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- FAM153B | c.621A>T p.T207= (on ENST00000253490; = p.T130= on NM_001265615.1) | Silent (SNP) | VAF 77/522 reads (15%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1677C>A p.T559= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- GABBR2 | c.948C>T p.G316= | Silent (SNP) | VAF 73/324 reads (23%) | catalogued as rs369085352; called by muse, mutect2, varscan2
- GABRQ | c.561G>C p.L187= | Silent (SNP) | VAF 78/311 reads (25%) | catalogued as COSV100941203, COSV64784308; called by muse, mutect2, varscan2
- GALNT12 | c.1690C>A p.R564= | Silent (SNP) | VAF 48/486 reads (10%) | catalogued as rs200145205; called by muse, mutect2
- GPM6A | c.225T>C p.F75= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs1444651522; called by muse, mutect2, varscan2
- HECTD4 | c.3555G>T p.S1185= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2
- HIC1 | c.900C>A p.A300= (on ENST00000322941 / NM_001098202.1; = p.A281= on NM_006497.4) | Silent (SNP) | VAF 69/330 reads (21%) | called by muse, mutect2, varscan2
- HIVEP1 | c.4350T>G p.S1450= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- HSP90AB1 | c.1509G>C p.V503= | Silent (SNP) | VAF 57/252 reads (23%) | called by muse, mutect2, varscan2
- IGKV1-9 | c.333A>G p.Q111= | Silent (SNP) | VAF 77/346 reads (22%) | catalogued as rs540942328; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1986C>A p.T662= | Silent (SNP) | VAF 44/243 reads (18%) | called by muse, mutect2, varscan2
- KCNK10 | c.867C>T p.G289= | Silent (SNP) | VAF 40/156 reads (26%) | called by muse, mutect2, varscan2
- KDM6A | c.1881C>T p.S627= | Silent (SNP) | VAF 81/302 reads (27%) | catalogued as rs1046565263; called by muse, mutect2, varscan2
- KRT25 | c.804G>A p.R268= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as rs776845203, COSV56446444; called by muse, mutect2, varscan2
- LILRB1 | c.1530G>T p.G510= (on ENST00000427581; = p.G460= on NM_006669.6) | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as COSV61118814; called by muse, varscan2
- LRIT1 | c.225T>C p.P75= | Silent (SNP) | VAF 59/200 reads (30%) | called by muse, mutect2, varscan2
- LRP1 | c.8328C>T p.P2776= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as rs1341627520; called by muse, mutect2, varscan2
- MAGEC1 | c.276C>A p.T92= | Silent (SNP) | VAF 91/364 reads (25%) | called by muse, mutect2, varscan2
- MAGT1 | c.450G>T p.R150= (on ENST00000618282 / NM_001367916.1; = p.R182= on NM_032121.5) | Silent (SNP) | VAF 112/408 reads (27%) | catalogued as COSV100800460; called by muse, mutect2, varscan2
- MARCO | c.702G>T p.G234= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as rs779048147, COSV100503787; called by muse, mutect2, varscan2
- MED27 | c.741C>T p.T247= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV52603367; called by muse, mutect2
- MROH2B | c.702G>T p.V234= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV68183249; called by muse, mutect2, varscan2
- MRPL40 | c.12C>A p.S4= | Silent (SNP) | VAF 30/112 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.41361C>T p.S13787= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV101110133; called by muse, mutect2, varscan2
- MUC17 | c.1377C>T p.V459= | Silent (SNP) | VAF 52/209 reads (25%) | called by muse, mutect2, varscan2
- MVK | c.354C>T p.S118= | Silent (SNP) | VAF 74/555 reads (13%) | called by muse, mutect2, varscan2
- MYH1 | c.3933C>A p.A1311= | Silent (SNP) | VAF 51/321 reads (16%) | called by muse, mutect2, varscan2
- MYH2 | c.3447G>T p.L1149= | Silent (SNP) | VAF 79/429 reads (18%) | called by muse, mutect2, varscan2
- MYLK3 | c.312G>C p.A104= | Silent (SNP) | VAF 73/301 reads (24%) | called by muse, mutect2, varscan2
- MYO16 | c.834G>A p.Q278= | Silent (SNP) | VAF 67/345 reads (19%) | called by muse, mutect2, varscan2
- NAV3 | c.2217C>A p.P739= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as COSV57067453, COSV57093650; called by muse, mutect2, varscan2
- NEXMIF | c.3228C>A p.T1076= | Silent (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- NFX1 | c.186T>C p.Y62= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as rs769042634; called by muse, mutect2, varscan2
- NPHS2 | c.129C>A p.P43= | Silent (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- OPRM1 | c.156G>T p.L52= | Silent (SNP) | VAF 45/234 reads (19%) | catalogued as COSV100002438; called by muse, mutect2, varscan2
- OR2A25 | c.927T>A p.T309= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- OR52B4 | c.279C>T p.D93= | Silent (SNP) | VAF 45/214 reads (21%) | called by muse, mutect2, varscan2
- OR56A1 | c.768C>T p.T256= | Silent (SNP) | VAF 17/91 reads (19%) | called by muse, mutect2, varscan2
- PARPBP | c.1329G>A p.K443= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- PCDH17 | c.2428C>A p.R810= | Silent (SNP) | VAF 45/176 reads (26%) | catalogued as rs147572809, COSV100931714; called by muse, mutect2, varscan2
- PCDHA13 | c.237G>A p.L79= | Silent (SNP) | VAF 94/509 reads (18%) | catalogued as rs782409687; called by muse, mutect2, varscan2
- PCDHGC3 | c.486C>G p.P162= | Silent (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- PLK1 | c.747A>C p.P249= | Silent (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- POLA1 | c.1428A>G p.V476= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs1175313264; called by muse, mutect2, varscan2
- POMT2 | c.1200C>T p.S400= | Silent (SNP) | VAF 108/514 reads (21%) | called by muse, varscan2
- PPP1R16B | c.27G>T p.T9= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs759901567; called by muse, mutect2, varscan2
- PRDM8 | c.870C>G p.G290= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as COSV60202709; called by muse, mutect2, varscan2
- PREP | c.1878A>G p.E626= (on ENST00000369110; = p.E692= on NM_002726.5) | Silent (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- PTPRQ | c.6252T>C p.S2084= (on ENST00000616559; = p.S2051= on NM_001145026.2) | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- REG1A | c.33C>A p.I11= | Silent (SNP) | VAF 21/132 reads (16%) | called by muse, mutect2, varscan2
- SGCZ | c.105A>G p.Q35= | Silent (SNP) | VAF 71/302 reads (24%) | catalogued as rs138373417; called by muse, mutect2, varscan2
- SGO2 | c.765C>T p.A255= | Silent (SNP) | VAF 35/132 reads (27%) | called by muse, mutect2, varscan2
- SHANK1 | c.177C>A p.G59= | Silent (SNP) | VAF 24/80 reads (30%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1417C>T p.L473= | Silent (SNP) | VAF 33/193 reads (17%) | called by muse, mutect2, varscan2
- SLC30A8 | c.201C>T p.Y67= | Silent (SNP) | VAF 116/448 reads (26%) | catalogued as rs750839622; called by muse, mutect2, varscan2
- SLC35B3 | c.1050G>T p.T350= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.1741C>T p.L581= | Silent (SNP) | VAF 70/355 reads (20%) | called by muse, mutect2, varscan2
- SRRM4 | c.666C>A p.S222= | Silent (SNP) | VAF 24/174 reads (14%) | catalogued as COSV99938547; called by muse, mutect2, varscan2
- TAAR1 | c.66C>A p.V22= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- TAOK3 | c.1314C>A p.I438= | Silent (SNP) | VAF 40/174 reads (23%) | catalogued as COSV66825043; called by muse, mutect2, varscan2
- TBR1 | c.1488G>A p.A496= | Silent (SNP) | VAF 57/281 reads (20%) | called by muse, mutect2, varscan2
- TBX20 | c.1143C>T p.H381= | Silent (SNP) | VAF 101/601 reads (17%) | catalogued as rs760014915; called by muse, mutect2, varscan2
- TCN1 | c.102C>A p.I34= | Silent (SNP) | VAF 72/371 reads (19%) | called by muse, mutect2, varscan2
- TNXB | c.8088C>T p.D2696= (on ENST00000647633; = p.D2449= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs747521071; called by muse, mutect2, varscan2
- TPRX1 | c.252C>T p.A84= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2940T>A p.S980= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1179284768; called by muse, mutect2, varscan2
- USH2A | c.4893T>A p.S1631= | Silent (SNP) | VAF 124/349 reads (36%) | called by muse, mutect2, varscan2
- WDR17 | c.2949A>T p.G983= | Silent (SNP) | VAF 27/416 reads (6%) | called by muse, mutect2
- ZCCHC7 | c.534A>C p.L178= | Silent (SNP) | VAF 67/307 reads (22%) | catalogued as rs1290037703; called by muse, mutect2, varscan2
- ZIC3 | c.381C>A p.L127= | Silent (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- ZNF208 | c.600C>T p.S200= | Silent (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
- ZNF335 | c.1995G>T p.L665= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- ZNF471 | c.114A>G p.L38= | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- ZNF729 | c.3078C>A p.V1026= | Silent (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- ZNRD2 | c.249T>C p.D83= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- ZWINT | c.576T>G p.L192= | Silent (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- AC099654.5 | n.66C>A | RNA (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- AC244517.10 | c.36-10731C>T | Intron (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2
- ADAMTS20 | c.4284+1728T>A | Intron (SNP) | VAF 55/345 reads (16%) | called by muse, mutect2, varscan2
- ALG2 | c.*1260A>G | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ANK2 | c.85-28545G>T | Intron (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- AQP3 | c.493-16T>C | Intron (SNP) | VAF 18/164 reads (11%) | catalogued as rs936949115; called by muse, mutect2, varscan2
- BLK | c.1030-187G>A | Intron (SNP) | VAF 46/182 reads (25%) | catalogued as rs532306352; called by muse, mutect2, varscan2
- CACNA1D | c.1478+331C>T | Intron (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- CFB | c.1624+95C>A | Intron (SNP) | VAF 28/278 reads (10%) | catalogued as COSV100191709; called by muse, mutect2
- CSNK1G1 | c.1108-7955A>G | Intron (SNP) | VAF 48/222 reads (22%) | called by muse, mutect2, varscan2
- DIPK2A | c.657+536T>A | Intron (SNP) | VAF 70/407 reads (17%) | called by muse, mutect2, varscan2
- DUSP18 | c.-77-1452A>T | Intron (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2437G>T | Intron (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- EIF4A1 | chr17:7572806 C>T | 5'Flank (SNP) | VAF 33/155 reads (21%) | catalogued as rs1471944781; called by muse, mutect2, varscan2
- FAM20A | c.*2007G>A | 3'UTR (SNP) | VAF 132/655 reads (20%) | called by muse, mutect2, varscan2
- FOXG1 | chr14:28772844 C>A | 3'Flank (SNP) | VAF 56/362 reads (15%) | catalogued as rs1428954849; called by muse, mutect2, varscan2
- FRMD8P1 | n.1237T>C | RNA (SNP) | VAF 64/219 reads (29%) | called by muse, mutect2, varscan2
- G6PC3 | c.-132G>C | 5'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- GAB3 | c.1645-756C>A | Intron (SNP) | VAF 14/38 reads (37%) | called by mutect2, varscan2
- GDAP1 | c.*1943A>G | 3'UTR (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- GFRA1 | c.*14A>G | 3'UTR (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- GPHN | c.143+28223A>C | Intron (SNP) | VAF 43/182 reads (24%) | called by muse, mutect2, varscan2
- HAND2-AS1 | n.512+1275G>T | Intron (SNP) | VAF 39/196 reads (20%) | catalogued as rs766667747; called by muse, mutect2, varscan2
- KCNC3 | chr19:50333837 G>C | 5'Flank (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- KLF3-AS1 | n.702+807G>T | Intron (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- KRT4 | c.834+48C>T | Intron (SNP) | VAF 98/270 reads (36%) | called by muse, mutect2, varscan2
- KRT80 | c.301-54T>G | Intron (SNP) | VAF 49/216 reads (23%) | catalogued as rs759007432; called by muse, mutect2, varscan2
- LGI4 | c.1299+60T>G | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, varscan2
- LINC01036 | n.386C>T | RNA (SNP) | VAF 50/106 reads (47%) | called by muse, varscan2
- LINC01148 | n.503A>T | RNA (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- LINC02413 | n.352+595G>T | Intron (SNP) | VAF 27/203 reads (13%) | catalogued as rs1203913994; called by muse, mutect2, varscan2
- LITAF | c.*1346G>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1999-31502A>T | Intron (SNP) | VAF 27/100 reads (27%) | called by mutect2, varscan2
- MAPK3 | c.1018-50G>T | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs376026029; called by muse, mutect2, varscan2
- MLIP | c.64-37878G>T | Intron (SNP) | VAF 75/320 reads (23%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92738G>T | Intron (SNP) | VAF 35/268 reads (13%) | called by muse, mutect2, varscan2
- MRRFP1 | n.381T>C | RNA (SNP) | VAF 30/133 reads (23%) | catalogued as rs760175051; called by muse, mutect2, varscan2
- NIPA1 | c.317+1454G>T | Intron (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2
- OR5E1P | n.549del | RNA (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- OR9Q1 | c.-15+53259C>T | Intron (SNP) | VAF 33/176 reads (19%) | catalogued as rs1232910614; called by muse, mutect2, varscan2
- PDE10A | c.106+91555G>T | Intron (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- POU4F3 | c.-28C>A | 5'UTR (SNP) | VAF 94/305 reads (31%) | catalogued as rs1411136967; called by muse, mutect2, varscan2
- PRAME | c.22-1828C>A | Intron (SNP) | VAF 48/218 reads (22%) | called by muse, mutect2, varscan2
- RHAG | c.*69G>T | 3'UTR (SNP) | VAF 88/450 reads (20%) | called by muse, mutect2, varscan2
- RPP30 | chr10:90902243 G>T | 3'Flank (SNP) | VAF 6/26 reads (23%) | catalogued as COSV65472001; called by muse, mutect2
- SERPINA13P | n.757G>A | RNA (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- SGCE | c.1361+32T>C | Intron (SNP) | VAF 73/324 reads (23%) | called by muse, mutect2, varscan2
- SMYD1 | c.*1559G>T | 3'UTR (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- SNORD115-41 | n.81C>A | RNA (SNP) | VAF 61/267 reads (23%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3712G>C | RNA (SNP) | VAF 80/407 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.14957C>A | RNA (SNP) | VAF 31/122 reads (25%) | called by muse, mutect2, varscan2
- ST8SIA6 | c.*2133T>G | 3'UTR (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- SYT16 | c.994-1458G>T | Intron (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- TMEM183B | n.109G>A | RNA (SNP) | VAF 74/331 reads (22%) | called by muse, mutect2, varscan2
- TRDMT1 | c.-2G>T | 5'UTR (SNP) | VAF 27/128 reads (21%) | catalogued as rs951392392; called by muse, mutect2, varscan2
- TTLL9 | c.70-7319C>A | Intron (SNP) | VAF 41/225 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.10360+1401C>A | Intron (SNP) | VAF 42/166 reads (25%) | catalogued as COSV100601535, COSV59902402; called by muse, mutect2, varscan2
- VNN3 | c.*598C>A | 3'UTR (SNP) | VAF 57/240 reads (24%) | called by muse, mutect2, varscan2
- ZNF204P | n.908G>T | RNA (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- ZNF395 | c.*1G>C | 3'UTR (SNP) | VAF 105/563 reads (19%) | called by muse, mutect2, varscan2
- ZNF99 | c.*234C>A | 3'UTR (SNP) | VAF 17/140 reads (12%) | catalogued as COSV101233902; called by muse, mutect2, varscan2
